Gene-level copy-number profile of tumor specimen TCGA-D5-5538-01A from TCGA case TCGA-D5-5538, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.2 years (21,974 days).
Specimen TCGA-D5-5538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.7e09c206-dc97-4bfe-bda5-997187a4e56a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-5538-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66ff6c74-9b16-4a3e-be85-26420958dfba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 6,890; copy number 2: 45,215; copy number 3: 7,707.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-5538-01A-01D-1649-01): tumor purity 0.69, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:45,274,359–45,569,069, 6 genes: RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
